Somatic mutation profile of tumor specimen TCGA-AA-3538-01A (aliquot TCGA-AA-3538-01A-01D-1953-10) from TCGA case TCGA-AA-3538, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 54.1 years (19,752 days).
Specimen TCGA-AA-3538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f23fefb-c161-436c-af79-bf1de3c3b27e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3538-10A (Blood Derived Normal), aliquot TCGA-AA-3538-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdbbd612-7959-4017-8731-b6a8502b6851

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD1 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99296099; called by muse, mutect2, varscan2
- C20orf194 | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99330375; called by muse, mutect2
- C2CD2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100995936; called by muse, mutect2, varscan2
- GAB4 | c.753T>A p.N251K | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101271902; called by muse, mutect2, varscan2
- GRB10 | c.848A>G p.N283S (on ENST00000398812; = p.N225S on NM_001001550.3) | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as COSV100239903; called by muse, mutect2, varscan2
- LRRC4B | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65349270; called by muse, mutect2, varscan2
- MED12 | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1371947595, COSV100376612; called by muse, mutect2
- PAPLN | c.727G>A p.A243T (on ENST00000554301; = p.A216T on NM_173462.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV99389239; called by muse, mutect2, varscan2
- SIPA1L3 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99727638; called by muse, mutect2, varscan2
- TLE4 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1215372546, COSV99511415; called by muse, varscan2
- TMTC4 | c.582A>C p.E194D (on ENST00000376234 / NM_001350577.2; = p.E213D on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.07); catalogued as COSV100168508; called by muse, mutect2, varscan2
- ARHGAP39 | c.2221_2223del p.K741del | In Frame Del (DEL) | VAF 92/162 reads (57%) | called by pindel, varscan2
- GHITM | c.220del p.I74Yfs*41 | Frame Shift Del (DEL) | VAF 64/241 reads (27%) | called by mutect2, pindel, varscan2
- PLEKHG3 | c.1502del p.P501Qfs*19 (on ENST00000394691; = p.P557Qfs*19 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 23/190 reads (12%) | called by mutect2, pindel, varscan2
- ARAF | c.1746G>A p.S582= | Silent (SNP) | VAF 60/106 reads (57%) | catalogued as rs905792014, COSV99283025; called by muse, mutect2, varscan2
- FAM81B | c.702C>T p.F234= | Silent (SNP) | VAF 72/159 reads (45%) | catalogued as COSV99352593; called by muse, mutect2, varscan2
- FCGBP | c.1434C>T p.P478= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- NOS1 | c.3678C>T p.D1226= | Silent (SNP) | VAF 90/316 reads (28%) | catalogued as rs781446114, COSV57608028; called by muse, mutect2, varscan2
- TLN2 | c.1383C>T p.S461= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs148665697; called by muse, varscan2
